Somatic mutation profile of tumor specimen TCGA-QU-A6IO-01A (aliquot TCGA-QU-A6IO-01A-11D-A31L-08) from TCGA case TCGA-QU-A6IO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.6 years (19,564 days).
Specimen TCGA-QU-A6IO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fbe69d9-3283-46eb-91a1-96d69c284263.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QU-A6IO-10A (Blood Derived Normal), aliquot TCGA-QU-A6IO-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d9889a8-e729-4272-ba4c-cd579c96a713

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 20, Silent 11, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B4 | c.2794C>A p.Q932K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52709251; called by muse, mutect2, varscan2
- EOMES | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55411031; called by muse, mutect2
- FCRL2 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as COSV63832552; called by muse, mutect2, varscan2
- FOXN2 | c.82T>C p.Y28H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV61317031; called by muse, mutect2, varscan2
- HOXD4 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1423935447, COSV60459302; called by muse, mutect2, varscan2
- KAT6A | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55902661; called by muse, mutect2, varscan2
- KPNA6 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV65359259; called by muse, mutect2, varscan2
- LIG4 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV63596436; called by muse, mutect2, varscan2
- LSP1 | c.99C>A p.H33Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV61132319; called by muse, mutect2, varscan2
- NLRP2 | c.2189T>G p.L730R | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV54752423; called by muse, mutect2
- OR10R2 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs768912180, COSV63768465; called by muse, mutect2
- OR4P4 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs747849915, COSV58920625, COSV58922652; called by muse, mutect2, varscan2
- PAX1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); catalogued as rs779219384, COSV68271089; called by muse, mutect2, varscan2
- PLPPR2 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768718298, COSV52258577; called by muse, mutect2, varscan2
- RBM39 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.694); catalogued as COSV53613770; called by muse, mutect2, varscan2
- RPH3A | c.1400G>A p.G467D (on ENST00000389385 / NM_001143854.2; = p.G463D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66989983; called by muse, mutect2
- STKLD1 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64311690; called by muse, mutect2
- TBCD | c.743T>C p.I248T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV62797657; called by muse, mutect2, varscan2
- TEX26 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100994040; called by muse, mutect2, varscan2
- YY1AP1 | c.397A>G p.M133V (on ENST00000295566 / NM_139118.2; = p.M56V on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV55119119; called by muse, mutect2, varscan2
- COG5 | c.2313-1G>A p.X771_splice (on ENST00000347053 / NM_001379512.1; = p.X792_splice on NM_006348.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- OR4C11 | c.894del p.K298Nfs*18 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- CPS1 | c.159A>T p.G53= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as COSV51802153; called by muse, mutect2, varscan2
- DEFB110 | c.106A>C p.R36= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs761565401, COSV64484314; called by muse, mutect2, varscan2
- DSN1 | c.906G>A p.L302= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs1469407759, COSV65518570; called by muse, mutect2, varscan2
- HNF4A | c.1140C>T p.S380= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as rs767934753, COSV57379772, COSV57380872; called by muse, mutect2, varscan2
- KRT27 | c.1011T>C p.S337= | Silent (SNP) | VAF 39/207 reads (19%) | catalogued as COSV56970761, COSV56972742; called by muse, mutect2, varscan2
- LAMC3 | c.1845C>T p.D615= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs746126039, COSV63088625; called by muse, mutect2, varscan2
- OR2T1 | c.267G>A p.R89= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as rs369495545; called by muse, mutect2
- PTRH1 | c.64T>C p.L22= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV58852057; called by muse, mutect2, varscan2
- SENP6 | c.810A>G p.L270= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV59189409; called by muse, mutect2, varscan2
- SIRT5 | c.411C>A p.V137= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV63079631; called by muse, mutect2, varscan2
- WNT3A | c.354C>T p.A118= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs151253698; called by muse, mutect2, varscan2
